Somatic mutation profile of tumor specimen TCGA-A3-3317-01A (aliquot TCGA-A3-3317-01A-01D-0966-08) from TCGA case TCGA-A3-3317, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 67.9 years (24,803 days).
Specimen TCGA-A3-3317-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d325ae84-8d2d-4d84-ae76-2bca62fc995b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3317-11A (Solid Tissue Normal), aliquot TCGA-A3-3317-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2844fc2f-3479-4579-9ea2-b51d95468b7b

The open-access MAF lists 81 somatic variants for this specimen: 58 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 20, Frame Shift Del 6, Nonsense Mutation 4, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMN | c.42C>T p.C14= | Splice Region (SNP) | VAF 8/13 reads (62%) | catalogued as rs747910380, COSV54487830; called by muse, mutect2
- ARMH3 | c.1397A>G p.D466G | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV64236239; called by muse, mutect2, varscan2
- BMX | c.958A>G p.M320V | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs923698155; called by muse, mutect2, varscan2
- CARS1 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1213967120; called by muse, mutect2, varscan2
- CHIT1 | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs779206133; called by muse, mutect2, varscan2
- CHRNA1 | c.1433T>A p.L478* (on ENST00000261007 / NM_001039523.3; = p.L453* on NM_000079.4) | Nonsense Mutation (SNP) | VAF 32/140 reads (23%) | catalogued as COSV53682480; called by muse, mutect2, varscan2
- CILP2 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs770419404, COSV52280282; called by muse, mutect2, varscan2
- ENPEP | c.1867C>T p.H623Y | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54447533; called by muse, mutect2, varscan2
- IPO4 | c.275C>G p.T92R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs778689897; called by muse, mutect2, varscan2
- KDM4B | c.2431A>T p.T811S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as rs905030316; called by muse, mutect2, varscan2
- PECR | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1171690553; called by muse, mutect2, varscan2
- PPP5C | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as rs1477627523; called by muse, mutect2
- PROP1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs768760285; called by muse, mutect2, varscan2
- PRPSAP1 | c.636G>C p.R212S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as rs745777762; called by muse, mutect2, varscan2
- SAMD7 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV59419327, COSV59421518; called by muse, mutect2, varscan2
- SLC6A5 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV54227035; called by muse, mutect2, varscan2
- SLC8A3 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs775830117, COSV100775835; called by muse, mutect2, varscan2
- VENTX | c.494C>A p.A165E | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as rs150065198; called by muse, mutect2, varscan2
- XPO4 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1183555563; called by muse, mutect2, varscan2
- ZFAND2B | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV54697445, COSV54698660; called by muse, mutect2, varscan2
- ACCS | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ANKRD36 | c.407A>T p.H136L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ARSB | c.1595G>A p.W532* | Nonsense Mutation (SNP) | VAF 54/217 reads (25%) | called by muse, mutect2, varscan2
- ATG2A | c.3046C>T p.Q1016* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- ATM | c.4110-4_4111del p.X1370_splice | Splice Site (DEL) | VAF 44/202 reads (22%) | called by mutect2, pindel, varscan2
- BAP1 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- C16orf71 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CBX8 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC181 | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH8 | c.1898T>G p.L633W | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DNAH3 | c.5735A>C p.H1912P | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, varscan2
- DNAJA3 | c.1422del p.K475Rfs*76 | Frame Shift Del (DEL) | VAF 36/172 reads (21%) | called by mutect2, pindel, varscan2
- DOCK7 | c.1640A>G p.E547G | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOK7 | c.592del p.C198Afs*48 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | called by mutect2, pindel, varscan2
- EIF2AK4 | c.3368C>G p.A1123G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, varscan2
- FASN | c.5386C>A p.L1796M | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELZ | c.150_159del p.L50Ffs*18 | Frame Shift Del (DEL) | VAF 58/309 reads (19%) | called by mutect2, pindel, varscan2
- HERC2 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF1C | c.2830C>G p.Q944E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- LINGO1 | c.1533C>A p.H511Q | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- LMO4 | c.260G>C p.C87S | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRFN3 | c.220G>C p.V74L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LYPD5 | c.317A>T p.D106V (on ENST00000377950 / NM_001031749.3; = p.D63V on NM_182573.2) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- NDUFS1 | c.252dup p.A85Sfs*3 | Frame Shift Ins (INS) | VAF 49/231 reads (21%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.1595G>A p.C532Y | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ORC1 | c.15del p.T6Qfs*3 | Frame Shift Del (DEL) | VAF 28/157 reads (18%) | called by mutect2, pindel, varscan2
- PCCA | c.1054A>T p.T352S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- RIF1 | c.4160A>C p.N1387T | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- SELENBP1 | c.1137+1G>C p.X379_splice | Splice Site (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- SLC6A5 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 95/378 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- STAG2 | c.2984del p.L995* | Frame Shift Del (DEL) | VAF 51/114 reads (45%) | called by mutect2, pindel, varscan2
- TBC1D15 | c.416A>G p.K139R | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TINF2 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TNPO2 | c.2298A>T p.E766D | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- TTC33 | c.455T>G p.V152G | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- WDR46 | c.1190C>T p.T397I | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, varscan2
- WDR46 | c.1189A>T p.T397S | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, varscan2
- ZNF304 | c.20del p.M7Rfs*8 | Frame Shift Del (DEL) | VAF 23/129 reads (18%) | called by mutect2, pindel
- ASIC1 | c.403C>T p.L135= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- CBLIF | c.138G>A p.S46= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs200472519; called by muse, mutect2, varscan2
- DMAP1 | c.672A>T p.R224= | Silent (SNP) | VAF 36/181 reads (20%) | called by muse, mutect2, varscan2
- DSC2 | c.1938T>C p.Y646= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as rs397517395; ClinVar: likely benign; called by muse, mutect2, varscan2
- ERAP1 | c.102C>T p.S34= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as rs769709894; called by muse, mutect2, varscan2
- FARP1 | c.2853G>A p.K951= | Silent (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- KIFC1 | c.1929G>T p.L643= | Silent (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- MBD1 | c.1398T>A p.P466= (on ENST00000269468 / NM_001323950.1; = p.P410= on NM_002384.2) | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs1398920953; called by muse, mutect2, varscan2
- MTHFSD | c.1003C>A p.R335= (on ENST00000360900 / NM_001159377.2; = p.R334= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- PCDHA5 | c.1284C>T p.D428= | Silent (SNP) | VAF 120/300 reads (40%) | catalogued as rs782621396, COSV65356090; called by muse, mutect2, varscan2
- PDLIM4 | c.759C>T p.P253= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as rs752956503, COSV99516834; called by muse, mutect2, varscan2
- PPP4R3B | c.1113A>T p.V371= | Silent (SNP) | VAF 77/306 reads (25%) | catalogued as rs199689343; called by muse, mutect2, varscan2
- PREPL | c.1575A>T p.L525= | Silent (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- RAC1 | c.573G>C p.L191= | Silent (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- SPCS3 | c.312C>T p.V104= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs569036179; called by muse, mutect2, varscan2
- ST6GAL2 | c.216G>C p.G72= | Silent (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- SUGP2 | c.705C>T p.L235= | Silent (SNP) | VAF 63/270 reads (23%) | catalogued as rs1568456353; called by muse, mutect2, varscan2
- TUSC3 | c.753C>T p.I251= | Silent (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- ZNF12 | c.966G>A p.E322= (on ENST00000405858 / NM_016265.4; = p.E284= on NM_006956.3) | Silent (SNP) | VAF 33/180 reads (18%) | called by muse, mutect2, varscan2
- ZNF221 | c.1716C>T p.G572= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as COSV52109114; called by muse, mutect2
- ABTB1 | c.*317C>A | 3'UTR (SNP) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- DLC1 | c.1348+90541G>T | Intron (SNP) | VAF 55/239 reads (23%) | called by muse, mutect2, varscan2
- MROH9 | c.-1C>T | 5'UTR (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
